Somatic mutation profile of tumor specimen MP2PRT-PAVULN-TMP1-A (aliquot MP2PRT-PAVULN-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVULN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,106 days).
Specimen MP2PRT-PAVULN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65d038c6-600e-44a3-8b39-a479f5555eb2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVULN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVULN-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffce001e-8732-4c1a-8fae-ff2dc2f02e64

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 10, Silent 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- P3H2 | c.1684C>T p.R562* | Nonsense Mutation (SNP) | VAF 51/241 reads (21%) | catalogued as rs772782439; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO9A | c.4439C>T p.T1480I | Missense Mutation (SNP) | VAF 38/287 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs762079265; called by muse, mutect2, varscan2
- ABCC9 | c.501C>G p.F167L | Missense Mutation (SNP) | VAF 94/290 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANAPC1 | c.3064G>A p.E1022K | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.037); called by muse, mutect2
- ARL5C | c.43C>G p.Q15E | Missense Mutation (SNP) | VAF 58/278 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP1B4 | c.583G>A p.E195K (on ENST00000218008 / NM_001142447.3; = p.E191K on NM_012069.5) | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.285); called by muse, mutect2
- CSMD3 | c.2984G>A p.G995D (on ENST00000297405 / NM_001363185.1; = p.G891D on NM_052900.3) | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRMPD4 | c.2728G>A p.E910K | Missense Mutation (SNP) | VAF 16/516 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LETM1 | c.1771T>C p.S591P | Missense Mutation (SNP) | VAF 78/226 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- PHF8 | c.1921C>G p.Q641E (on ENST00000357988 / NM_001184896.1; = p.Q605E on NM_015107.3) | Missense Mutation (SNP) | VAF 20/576 reads (3%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- THBS4 | c.2818T>A p.C940S | Missense Mutation (SNP) | VAF 92/236 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIF26B | c.3150C>G p.L1050= | Silent (SNP) | VAF 20/702 reads (3%) | called by muse, mutect2
- TAF1 | c.279C>T p.I93= | Silent (SNP) | VAF 97/365 reads (27%) | catalogued as COSV52107315; called by muse, mutect2, varscan2
- TENM2 | c.1923C>T p.I641= (on ENST00000518659 / NM_001122679.2; = p.I409= on NM_001080428.3) | Silent (SNP) | VAF 114/320 reads (36%) | catalogued as rs758662883; called by muse, mutect2, varscan2
- TMEM121B | c.1287C>T p.I429= | Silent (SNP) | VAF 44/649 reads (7%) | called by muse, mutect2
- VAX1 | c.105G>A p.A35= | Silent (SNP) | VAF 106/321 reads (33%) | catalogued as rs373928197; called by muse, mutect2, varscan2
- ZADH2 | c.153G>C p.L51= | Silent (SNP) | VAF 171/521 reads (33%) | called by muse, mutect2, varscan2
